Somatic mutation profile of tumor specimen TCGA-77-8008-01A (aliquot TCGA-77-8008-01A-21D-2184-08) from TCGA case TCGA-77-8008, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.3 years (24,948 days).
Specimen TCGA-77-8008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b065e0a7-5563-4b1f-9dbe-62638641aec6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8008-11A (Solid Tissue Normal), aliquot TCGA-77-8008-11A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c0ee06f-55d2-4638-9e20-25f9d1e9d6fc

The open-access MAF lists 183 somatic variants for this specimen: 123 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 53, Nonsense Mutation 10, Frame Shift Del 4, Splice Site 4, Intron 3, 5'Flank 2, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.14590G>T p.G4864C | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553339086, COSV100772732; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV99447631; called by muse, mutect2, varscan2
- ADAMTS5 | c.2690C>A p.T897N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV99538297; called by muse, mutect2
- ADTRP | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV99995494; called by muse, mutect2, varscan2
- AKR1C1 | c.359T>A p.V120E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV101080566; called by muse, mutect2, varscan2
- ALS2 | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99970035; called by muse, mutect2, varscan2
- ANAPC2 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs1564380467, COSV100119226; called by muse, mutect2, varscan2
- ANKRD50 | c.4252G>T p.D1418Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101539044; called by muse, mutect2, varscan2
- ARC | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100751777; called by muse, mutect2, varscan2
- ARID3C | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV99427040; called by muse, mutect2, varscan2
- ASB9 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV100995574; called by muse, mutect2, varscan2
- ATRNL1 | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.305); catalogued as COSV100372711, COSV58075402; called by muse, mutect2, varscan2
- ATXN1 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs779064972, COSV99787680; called by muse, mutect2, varscan2
- C14orf28 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57333068; called by muse, mutect2, varscan2
- C4orf45 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV101465177; called by muse, mutect2
- CACNA1I | c.2617C>A p.R873S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100359813, COSV100361482; called by muse, mutect2, varscan2
- CADM3 | c.769C>A p.R257S (on ENST00000368125 / NM_001127173.3; = p.R291S on NM_021189.5) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV100930408; called by muse, mutect2, varscan2
- CASZ1 | c.3133T>A p.L1045M | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100682145; called by muse, mutect2
- CDC73 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100813983; called by muse, mutect2
- CDH19 | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1224027654, COSV100052290; called by muse, mutect2, varscan2
- CFAP91 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV56344792, COSV99847481; called by muse, mutect2
- CLPB | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as COSV99578656; called by muse, mutect2, varscan2
- COL19A1 | c.2422A>T p.K808* | Nonsense Mutation (SNP) | VAF 31/213 reads (15%) | catalogued as COSV100507453; called by muse, mutect2, varscan2
- COL8A1 | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV99658427; called by muse, mutect2, varscan2
- COMMD8 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.163); catalogued as COSV101055776; called by muse, mutect2, varscan2
- CPNE2 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99321601; called by muse, mutect2, varscan2
- CRYBG3 | c.8366G>T p.W2789L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV99477457; called by muse, mutect2, varscan2
- DCT | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100986302, COSV65468992; called by muse, mutect2
- DEFB110 | c.110T>A p.I37K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100953816; called by muse, mutect2
- DEFB118 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs142729979, COSV53621276; called by muse, mutect2, varscan2
- DIAPH3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99934445; called by muse, mutect2, varscan2
- DLEC1 | c.4230G>T p.M1410I | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100343415; called by muse, mutect2, varscan2
- DNAH3 | c.4867G>T p.E1623* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV54532747, COSV99770442; called by muse, mutect2, varscan2
- DOCK4 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV70325946; called by muse, mutect2, varscan2
- DRD3 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55680799, COSV99879676; called by muse, mutect2, varscan2
- ECEL1 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459001; called by muse, mutect2
- EPHA7 | c.2373T>A p.Y791* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100994317; called by muse, mutect2, varscan2
- ERBIN | c.4178C>T p.S1393F (on ENST00000284037 / NM_001253697.2; = p.S1352F on NM_018695.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99397767; called by muse, mutect2, varscan2
- ESRRG | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100753839, COSV63161564; called by muse, mutect2, varscan2
- F2 | c.1533G>T p.W511C | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61318185; called by muse, mutect2, varscan2
- FAT3 | c.10823T>C p.L3608P | Missense Mutation (SNP) | VAF 23/407 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as COSV99970728; called by muse, mutect2
- FZD9 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV100290113; called by muse, mutect2, varscan2
- GABRG1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99778701; called by muse, mutect2, varscan2
- GIGYF1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99309974; called by muse, mutect2, varscan2
- GLRA3 | c.1363A>T p.R455W | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV99928148; called by muse, mutect2, varscan2
- GMEB1 | c.1082A>T p.Q361L | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99603456; called by muse, mutect2, varscan2
- GPR31 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100834170; called by muse, mutect2, varscan2
- GRID1 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.43); catalogued as rs375701164; called by muse, mutect2, varscan2
- ITGB3 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1446324978, COSV101457668; called by muse, mutect2
- ITPRID1 | c.1586C>A p.T529K | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.098); catalogued as COSV100087447; called by muse, mutect2, varscan2
- JMJD1C | c.5197G>T p.E1733* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100550824; called by muse, mutect2, varscan2
- KCNJ5 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1430519737, COSV100610800; called by muse, mutect2
- KCTD10 | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as COSV99949423; called by muse, mutect2, varscan2
- KIRREL1 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100780099; called by muse, mutect2
- LAMA1 | c.4871A>T p.E1624V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV101057656; called by muse, mutect2, varscan2
- MAGI2 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV62638503, COSV99073975; called by muse, mutect2, varscan2
- MAPK4 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101245964; called by muse, mutect2, varscan2
- MGAM | c.3053A>C p.D1018A | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV101527736; called by muse, mutect2, varscan2
- MYH8 | c.5209G>A p.V1737I | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs775814737, COSV67959450; called by muse, mutect2, varscan2
- MYO3B | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100511673; called by muse, mutect2, varscan2
- MYT1L | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV101221399, COSV67725672; called by muse, mutect2
- NAAA | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as rs764183096, COSV99716126; called by muse, mutect2, varscan2
- NEBL | c.1557C>A p.S519R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1353151177, COSV101009347; called by muse, mutect2, varscan2
- OR10J3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV100171874; called by muse, mutect2, varscan2
- OR11H12 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV73569316; called by muse, mutect2
- OR12D3 | c.108C>A p.N36K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101011231, COSV101011459; called by muse, mutect2
- OR2A12 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV101283206; called by muse, mutect2, varscan2
- OR2T34 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60901508; called by muse, mutect2, varscan2
- OR4L1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1408825453, COSV100235900; called by muse, mutect2, varscan2
- OR51F1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as COSV100598901; called by muse, mutect2, varscan2
- OR51G1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV100429417; called by muse, mutect2
- OR8D4 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 15/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58431930; called by muse, mutect2
- PDCD2L | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99875139; called by muse, mutect2, varscan2
- PELO | c.22A>T p.I8F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV99252111; called by muse, mutect2, varscan2
- PIKFYVE | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs374472118; called by muse, mutect2, varscan2
- PLCH1 | c.2245G>T p.D749Y (on ENST00000340059 / NM_001130960.2; = p.D761Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100398172; called by muse, mutect2, varscan2
- PLS1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100538334; called by muse, mutect2, varscan2
- PNLIPRP3 | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100982609; called by muse, mutect2, varscan2
- PTPRA | c.-584G>C | Splice Region (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100988612; called by muse, mutect2, varscan2
- RBM15 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100873505; called by muse, mutect2, varscan2
- REG3A | c.458C>A p.T153K | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100532911; called by muse, mutect2, varscan2
- RGS20 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 22/176 reads (13%) | catalogued as COSV99810035; called by muse, mutect2, varscan2
- RHOBTB1 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558674; called by muse, mutect2, varscan2
- RSPH6A | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55572194; called by muse, mutect2, varscan2
- SACS | c.9253G>T p.D3085Y | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV101207538, COSV101207714; called by muse, mutect2
- SERTM1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100171496; called by muse, mutect2, varscan2
- SFTPB | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs1289542876, COSV100667302; called by muse, mutect2
- SGK3 | c.1272G>T p.W424C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616860; called by muse, mutect2, varscan2
- SH3TC2 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100102313; called by muse, mutect2, varscan2
- SHROOM4 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99174562; called by muse, mutect2, varscan2
- SLC12A2 | c.759A>G p.E253= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99321507; called by muse, mutect2, varscan2
- SLC6A17 | c.1546G>T p.G516* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV58992223, COSV58995777; called by muse, mutect2, varscan2
- SNX19 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779185353, COSV99772963, COSV99773586; called by muse, mutect2, varscan2
- STIM1 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV100331000; called by muse, mutect2, varscan2
- STK32C | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100063418; called by muse, mutect2, varscan2
- STMN2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99626851; called by muse, mutect2, varscan2
- STRA6 | c.720+1G>T p.X240_splice | Splice Site (SNP) | VAF 33/146 reads (23%) | catalogued as COSV100121286; called by muse, mutect2, varscan2
- SUN1 | c.1532C>A p.T511K (on ENST00000405266 / NM_001367651.1; = p.T391K on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101273067; called by mutect2, varscan2
- SYTL2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | catalogued as COSV100314931; called by muse, mutect2
- TENM4 | c.7276G>A p.G2426R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368652809; called by muse, mutect2, varscan2
- TFDP3 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100033534; called by muse, mutect2, varscan2
- TFPT | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100338298, COSV57838362; called by muse, mutect2
- TLR5 | c.1722G>T p.L574F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100643383; called by muse, mutect2, varscan2
- TMEM121B | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100083435; called by muse, mutect2, varscan2
- TTN | c.28240T>C p.W9414R (on ENST00000591111; = p.W8487R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100628911; called by muse, mutect2, varscan2
- TTN | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen benign (0); catalogued as COSV100628912; called by muse, mutect2, varscan2
- VWA3B | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as COSV101346159; called by muse, mutect2, varscan2
- WDR7 | c.2125A>G p.R709G | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV99590375; called by muse, mutect2
- ZDHHC21 | c.622-1G>A p.X208_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101099390, COSV66614337; called by muse, mutect2
- ZFP28 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100019873; called by muse, mutect2, varscan2
- ZFR | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV99416499; called by muse, mutect2, varscan2
- ZNF335 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs774100033, COSV59818676; called by muse, mutect2
- ZNF423 | c.3167G>T p.G1056V (on ENST00000563137 / NM_001379286.1; = p.G1048V on NM_015069.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV99283664; called by muse, mutect2, varscan2
- ZNF532 | c.2714A>G p.Y905C | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs371153903; called by muse, mutect2, varscan2
- ZNF676 | c.1616G>T p.C539F (on ENST00000650058; = p.C507F on NM_001001411.3) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101236343; called by muse, mutect2, varscan2
- ZNF836 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV100441249; called by muse, mutect2, varscan2
- FAT1 | c.1853del p.N618Tfs*9 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- INHBA | c.818del p.G273Afs*86 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- OR8G2P | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); called by muse, mutect2
- PLD5 | c.1204dup p.I402Nfs*4 (on ENST00000442594; = p.I340Nfs*4 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- SCN2A | c.1270del p.V424Wfs*30 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel*, varscan2
- SLC35F3 | c.211del p.A71Rfs*19 (on ENST00000366617 / NM_001300845.1; = p.A140Rfs*19 on NM_173508.4) | Frame Shift Del (DEL) | VAF 42/220 reads (19%) | called by mutect2, pindel, varscan2
- ABCB1 | c.2775G>A p.Q925= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV99714297; called by muse, mutect2, varscan2
- ADD1 | c.1791A>G p.K597= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99296957; called by muse, mutect2
- ANGPT1 | c.1272T>C p.D424= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99864096; called by muse, mutect2, varscan2
- C16orf71 | c.1173C>A p.S391= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99556522; called by muse, mutect2, varscan2
- CNIH3 | c.378C>T p.D126= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV99686233; called by muse, mutect2, varscan2
- CNOT1 | c.5232T>G p.L1744= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99801145; called by muse, varscan2
- COL11A1 | c.1101C>A p.G367= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100617973, COSV62189123; called by muse, mutect2
- DAAM2 | c.2959C>A p.R987= (on ENST00000274867 / NM_001201427.2; = p.R986= on NM_015345.3) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99226924; called by muse, mutect2, varscan2
- DCST1 | c.1305T>C p.A435= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV99793042, COSV99793607; called by muse, mutect2, varscan2
- DDO | c.414C>A p.T138= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100927899; called by muse, mutect2
- DENND10 | c.552G>T p.V184= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100814042; called by muse, mutect2, varscan2
- DGAT1 | c.957C>T p.I319= | Silent (SNP) | VAF 17/324 reads (5%) | catalogued as rs782237918, COSV60047346; called by muse, mutect2
- DOK6 | c.576G>A p.T192= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as rs370000347; called by muse, mutect2
- DYNAP | c.546T>C p.S182= (on ENST00000321600; = p.S156= on NM_173629.3) | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as COSV100391880; called by muse, mutect2, varscan2
- EFCAB3 | c.975T>C p.T325= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV100540476; called by muse, mutect2, varscan2
- EMILIN2 | c.591G>C p.T197= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs200834200, COSV54422656, COSV99598884; called by muse, mutect2, varscan2
- FAT4 | c.5730A>G p.Q1910= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1331856526, COSV100630064; called by muse, mutect2
- FGF5 | c.219C>T p.G73= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- FOXG1 | c.936C>T p.P312= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as rs1555321376, COSV100487059; ClinVar: likely benign; called by muse, mutect2, varscan2
- GCK | c.426G>A p.K142= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV60787520; called by muse, mutect2
- HLA-DRB5 | c.645G>A p.V215= | Silent (SNP) | VAF 61/419 reads (15%) | catalogued as COSV100894630; called by muse, mutect2, varscan2
- INMT | c.429C>A p.V143= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99185138; called by muse, mutect2, varscan2
- KIF14 | c.1008C>T p.P336= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs1429798162, COSV66263199; called by muse, mutect2
- LRP1B | c.8838G>T p.P2946= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV101260549, COSV67214609; called by muse, mutect2, varscan2
- MAGEB4 | c.681G>T p.L227= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100975102; called by muse, mutect2, varscan2
- NCAN | c.3489G>T p.G1163= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99388261; called by muse, mutect2, varscan2
- NEK11 | c.1770C>T p.Y590= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV101273022; called by muse, mutect2, varscan2
- NLRP5 | c.594T>A p.G198= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV101173867; called by muse, mutect2
- NOTCH4 | c.1882C>T p.L628= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100900995; called by muse, mutect2, varscan2
- OR2L3 | c.657G>C p.R219= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as COSV100742049, COSV63454392; called by muse, mutect2, varscan2
- OR2T34 | c.489G>A p.L163= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100170457; called by muse, mutect2, varscan2
- OR4C46 | c.636G>A p.L212= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100060738, COSV100060978; called by muse, mutect2
- PAK6 | c.1429C>T p.L477= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as COSV53045478; called by muse, mutect2
- PCDHA9 | c.1914C>T p.D638= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs868952983, COSV65326170; called by muse, mutect2, varscan2
- PCLO | c.13572G>T p.P4524= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100428940, COSV100437487; called by muse, mutect2, varscan2
- PDGFB | c.702A>T p.A234= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100483600; called by muse, mutect2, varscan2
- PKHD1 | c.10627T>C p.L3543= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100945329; called by muse, mutect2, varscan2
- POLH | c.1227T>C p.S409= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100947881; called by muse, mutect2, varscan2
- PPFIA1 | c.2547G>T p.G849= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV99558010; called by muse, mutect2
- PTPN3 | c.969G>A p.Q323= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1255193591, COSV99356205; called by muse, mutect2, varscan2
- SALL1 | c.2571C>A p.P857= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV99183769; called by muse, mutect2, varscan2
- SF3B1 | c.384T>A p.I128= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as COSV100135724; called by muse, mutect2, varscan2
- SHCBP1 | c.1965G>T p.V655= | Silent (SNP) | VAF 64/401 reads (16%) | catalogued as COSV100317526; called by muse, mutect2, varscan2
- SIN3A | c.3648A>G p.K1216= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as COSV99145809; called by muse, mutect2, varscan2
- SLC37A1 | c.1191C>T p.C397= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs780937577, COSV100721822; called by muse, mutect2, varscan2
- SLC6A15 | c.1875G>T p.L625= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV99881492; called by muse, mutect2, varscan2
- SMG1 | c.1128C>T p.S376= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101246779; called by muse, mutect2, varscan2
- SPATA31D1 | c.2488C>T p.L830= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs778974980; called by muse, mutect2, varscan2
- SPECC1L | c.2790A>G p.P930= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as rs200759886, COSV100063207; called by muse, mutect2
- SRPK1 | c.1446C>T p.P482= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100644449; called by muse, mutect2, varscan2
- STK31 | c.771G>T p.G257= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as rs1294337480, COSV100669927; called by muse, mutect2, varscan2
- TEX26 | c.408C>T p.N136= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100994139; called by muse, mutect2
- ZIC1 | c.1272C>A p.P424= | Silent (SNP) | VAF 40/151 reads (26%) | catalogued as rs368298985, COSV99292396; called by muse, mutect2, varscan2
- CTBP1 | chr4:1250704 G>T | 5'Flank (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- DPP6 | c.*332C>T | 3'UTR (SNP) | VAF 16/125 reads (13%) | catalogued as rs752831233, COSV100122481; called by muse, mutect2, varscan2
- KIR3DX1 | n.780A>T | RNA (SNP) | VAF 36/152 reads (24%) | catalogued as COSV99683631; called by muse, mutect2, varscan2
- MICD | chr6:29975214 C>A | 5'Flank (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NOP56 | c.569+181A>G | Intron (SNP) | VAF 23/137 reads (17%) | catalogued as COSV100250328; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+625C>G | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99198646; called by muse, mutect2
- TTN | c.10361-3771A>T | Intron (SNP) | VAF 14/127 reads (11%) | catalogued as COSV100592216; called by muse, mutect2
